Somatic mutation profile of tumor specimen 0D9S44 from CCDI case PBBIUC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,762 days).
Specimen 0D9S44: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d8958b6-08a3-4990-ba30-5ffd7fcc8769.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9S2X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ebac46f-62a4-443e-9e90-132bb08d41b2

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF23 | c.459G>A p.P153= | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as rs183357688; called by muse, mutect2
- H3-5 | c.-39G>A | 5'UTR (SNP) | VAF 20/76 reads (26%) | catalogued as rs755384853, COSV100461848; called by muse, varscan2
